EXCEPTIONAL_RESPONDERS case ER-ABCU — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/edce33bd-6c71-4b0c-88f0-bb78da70d8ae

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1950; Vital status: Dead; Days to death: 2,441 days (6.7 years); Year of death: 2015.

Diagnoses (1)
1. Duct adenocarcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 57.7 years (21,058 days); Year of diagnosis: 2008; Prior malignancy: no; Days to last follow up: 1,405 days (3.8 years); Days to best overall response: 261 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Capecitabine; Days to treatment start: 121 days; Days to treatment end: 283 days.

Follow-up (1 entry)
- Days to follow up: 1,405 days (3.8 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 1,405 days (3.8 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABCU-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABCU-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 5; Percent normal cells: 65; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.
- Sample ER-ABCU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABCU-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 15; Percent tumor nuclei: 5; Percent normal cells: 85; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 5.
